Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A83T, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A83T-01A (Primary Tumor).

[page 1 of 3]
Encounter Date: (

Results

SURGICAL PATHOLOGY

Patient Info

Patient Name

Sex

DOB

Component Results

Surgical Pathology Report:

Specimen #:

Physician:

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site (L) Kidney NOS C64.9
Jr 10/17/13

FINAL DIAGNOSIS

1. LEFT KIDNEY, RADICAL NEPHRECTOMY - RENAL CELL CARCINOMA, PAPILLARY TYPE, FURHMAN NUCLEAR GRADE 2 OF 4 (4.1 CM IN GREATEST DIMENSION). SEE COMMENT.

- TUMOR IS CONFINED TO THE KIDNEY.
- NO VASCULAR INVASION PRESENT.
- ALL SURGICAL MARGINS, INCLUDING VASCULAR, URETERAL AND PERINEPHRIC SOFT TISSUE, ARE NEGATIVE.
- ADRENAL GLAND NEGATIVE FOR TUMOR.

COMMENT

This tumor focally has clear cell changes. By immunohistochemistry, these clear cells are negative for cytokeratin 7, similar to conventional clear cell RCC, while the rest of the papillary RCC is positive for this marker. The significance of finding a small component of clear cell RCC in an otherwise papillary RCC is unknown.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Electronic Signature

SPECIMEN SUBMITTED

A: LEFT KIDNEY

CLINICAL DATA

LEFT KIDNEY LESION

GROSS DESCRIPTION

A. The specimen consists of a left kidney surrounded by an envelope of fibroadipose tissue measuring in total 21.5 x 8.5 x 7.5 cm, and weighing 1,224.25 grams. The kidney measures 11.5 x 5.5 x 4.5 cm. At the

[page 2 of 3]
[REDACTED]

inferior pole of the specimen, a 5.0 cm in diameter area of exposed capsule is apparent. Underlying this is a 4.1 x 4.0 x 4.0 mass which extends from the inferior pole of the kidney. On sectioning, the mass has a variegated, yellow-red, soft and focally hemorrhagic cut surface. It appears well-circumscribed and does not appear to extend into the perirenal fat or renal sinus, and is not present at the soft tissue margin of the specimen. The closest soft tissue margin is approximately 2 cm from the tumor. Satellite nodules of tumor are not present in the renal tissue. Dissection of the renal veins does not show intravascular presence of neoplasm. The renal parenchyma is pale, with blurred corticomedullary demarcations. There is one large cyst present in the superior pole and several much smaller cysts scattered throughout the renal parenchyma. The cysts are lined by a smooth wall and are filled with clear fluid. The largest cyst measures 2.0 cm in largest diameter and the smaller cysts range in size from 0.2 to 0.5 cm in diameter. A partially fragmented adrenal gland is visible on the surface of the specimen measuring 5.5 x 1.2 x 1.0 cm and weighing 5.6 grams. The adrenal is without nodules but is somewhat hemorrhagic. It does not appear involved by the mass, and the closest portion of mass is approximately 7 cm distant. A 5.0 cm segment of ureter is present and is essentially unremarkable. Lymph nodes are not present. Representative sections are submitted as follows: A1 frozen section no charge; A2 vascular margins and ureter margin; A3 representative sections of adrenal; A4 & A5 tumor nearest soft tissue margin; A6 tumor nearest renal sinus; A7 tumor nearest renal pelvis; A8 tumor and adjacent kidney; A9 tumor; A10 representative section normal kidney and representative section of kidney with cysts.

Patient ID #: [REDACTED]
DOB: [REDACTED]
Date of Report:
Date of Procedure:
Date of Receipt:
Submitted by:
Location:

Lab and Collection

SURGICAL PATHOLOGY ([REDACTED]) on _____

Result History

SURGICAL PATHOLOGY ([REDACTED]) on _____ Order Result History Report.

Result Information

Result Date and Time

Status
Final result

Provider Status
Reviewed

Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Kidney renal papillary cell carcinoma - (Kidney renal papillary cell carcinoma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

renal cell carcinoma

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

papillary type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

confirmation of clarification of KIRP Type II provided in discrepancy note

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file f8da3a66-2a13-4351-923e-cd3e70e98b95 (TCGA-IA-A83T.0985E4C5-CCC0-49A3-8604-8E0021AEB435.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).